HCMI case HCM-BROD-0925-C71 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d230be66-fdb1-463f-90d6-484a6e968277

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1956; Vital status: Alive.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 59.6 years (21,761 days); WHO CNS grade: Grade IV; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: No.
   Pathology details: Necrosis present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,515 days (4.1 years); Days to treatment end: 1,675 days (4.6 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,780 days (4.9 years); Days to treatment end: 1,801 days (4.9 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: recurrence; Age at diagnosis: 63.8 years (23,290 days); Days to diagnosis: 1,529 days (4.2 years).
   Pathology details: Necrosis present: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Temozolomide; Treatment intent type: Maintenance Therapy; Days to treatment start: 31 days; Days to treatment end: 1,515 days (4.1 years); Treatment outcome: Treatment Ongoing.

Follow-up (5 entries)
- Days to follow up: 21 days; ECOG performance status: 2.
- Days to follow up: 21 days; ECOG performance status: 1.
- Days to follow up: 74 days; Karnofsky performance status: 90.
- Days to follow up: 1,827 days (5.0 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 1,780.

Molecular and laboratory tests
- IDH1 (IHC): Equivocal; Amino-acid change: R132H.
- IDH1 (IHC): Negative; Amino-acid change: R132H.
- IDH1 / IDH2 (Targeted Sequencing): Negative.
- MGMT methylation: Positive.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80 kg; Height: 173 cm; BMI: 26.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-BROD-0925-C71-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0925-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 5.
